Surgical pathology report (de-identified scan), TCGA case TCGA-FE-A23A, project TCGA-THCA (Thyroid Carcinoma), tissue source site Ohio State University, specimen TCGA-FE-A23A-01A (Primary Tumor).

[page 1 of 4]
Dual/Synchronous Primary	Noted	

Sex: F

Specimen Description

Surgical Pathology Report

*****Clinical History*****

Patient History: Papillary CA of thyroid.

*****Final Pathologic Diagnosis*****

Midline neck lymph node, excision:

Lymph node (0/1), no tumor seen.

Right paratracheal lymph node, excision:

Lymph nodes (0/3), no tumor seen.

Midline neck lymph node, excision:

Lymph nodes (0/6), no tumor seen.

Thyroid gland, total thyroidectomy:

Papillary thyroid carcinoma with oxyphilic changes (see synoptic report).

Lymph nodes (0/2), no tumor seen.

Hashimoto's thyroiditis.

Right paratracheal lymph node, excision:

Lymph nodes (0/1), no tumor seen.

100-0-3

carcinoma, papillary, thyroid 8200/3
Site: thyroid, NOS c73.9 lw 4/8/11

*****Synoptic Report*****

SYNOPTIC REPORT FOR THYROID CANCER:

Specimen type: Total thyroidectomy.

Tumor location: Right lobe.

Tumor size: 2.7 x 2.2 x 2.0 cm.

Histologic type: Papillary carcinoma.

Tumor grade: Well-differentiated.

Lymphatic/vascular invasion: Yes.

Capsular invasion: No.

[page 2 of 4]
Print this Page**Specimen Description****Surgical Pathology Report**

Patient Name: [REDACTED]
Accession #: [REDACTED]
Med. Rec #: [REDACTED]
Submitting Physician: [REDACTED]

*******Clinical History*******

Patient History: Papillary CA of thyroid.

*******Final Pathologic Diagnosis*******

- A. Midline neck lymph node, excision:
- Lymph node (0/1), no tumor seen.
- B. Right paratracheal lymph node, excision:
- Lymph nodes (0/3), no tumor seen.
- C. Midline neck lymph node, excision:
- Lymph nodes (0/6), no tumor seen.
- D. Thyroid gland, total thyroidectomy:
- Papillary thyroid carcinoma with oxyphilic changes (see synoptic report).
- Lymph nodes (0/2), no tumor seen.
- Hashimoto's thyroiditis.
- E. Right paratracheal lymph node, excision:
- Lymph nodes (01), no tumor seen.

[REDACTED]
Electronically Signed By
[REDACTED]
[REDACTED]

*******Synoptic Report*******

SYNOPTIC REPORT FOR THYROID CANCER:
Specimen type: Total thyroidectomy.
Tumor location: Right lobe.
Tumor size: 2.7 x 2.2 x 2.0 cm.
Histologic type: Papillary carcinoma.
Tumor grade: Well-differentiated.
Lymphatic/vascular invasion: Yes.
Capsular invasion: No.

[page 3 of 4]
Tumor extent:
Confined to the thyroid: Yes.
Multifocal: No.
Invasion of thyroid cartilage or hyoid bone: No.
Infiltration of adjacent structures: No.
Lymph nodes:
Total number examined: 13
Sites/laterality: Bilateral.
Number positive: 0
Number negative: 13
Additional pathologic findings: Hashimoto's thyroiditis.
pTNM: pT2N0Mx.

The above synoptic report complies, in slightly modified form, with the guidelines of the College of American Pathologists and the Association of Directors of Anatomic and Surgical Pathology for the reporting of cancer specimens

*****INTRAOPERATIVE CONSULTATION DIAGNOSIS:*****

- [REDACTED] Midline neck node: (FROZEN SECTION PERFORMED)
Benign.
[REDACTED] RT paratracheal nodes: (FROZEN SECTION PERFORMED)
Benign.
[REDACTED] Midline neck nodes: (FROZEN SECTION PERFORMED)
Benign.
[REDACTED] Total thyroid: (FROZEN SECTION PERFORMED)
Papillary thyroid carcinoma.

Examining pathologist: [REDACTED]

*****SPECIMEN(S) RECEIVED:*****

[REDACTED] Lymph node, ENT, REG
[REDACTED] Lymph node, ENT, REG
[REDACTED] Lymph node, ENT, REG
[REDACTED] Thyroid, REG
[REDACTED] Lymph node, ENT, REG

*****GROSS DESCRIPTION:*****

The specimens are received in five properly labeled containers, four of which are frozen sections, with the patient's name and accession number.

[REDACTED] The specimen is designated "midline neck node" and consists of a 0.7 x 0.6 x 0.3 cm tan-pink lymph node. The specimen is entirely submitted for frozen section and resubmitted as received in cassette AF1.
TE 1

[REDACTED] The specimen is designated "RT paratracheal nodes" and consists of a 1.2 x 1.0 x 0.7 cm aggregate of tan-red soft tissue. Upon dissection

[page 4 of 4]
reveals five lymph nodes ranging from 0.2 cm up to 0.7 cm in greatest dimension. The lymph nodes are entirely submitted for frozen section and resubmitted as received in cassette BF1. TE 1

■ The specimen is designated "midline neck nodes" and consists of a 2.1 x 1.4 x 0.5 cm aggregate of tan-red soft tissue that reveals six lymph nodes ranging from 0.3 to 0.9 cm in greatest dimension. The specimen is entirely submitted for frozen section and resubmitted as received in cassette CF1. TE 1

■ The specimen is designated "total thyroid" and consists of a 25.9 gram total thyroid that is 5.5 x 5.0 x 2.3 cm. The external surface is tan-red and slightly shaggy with no parathyroid tissue or lymph nodes identified. The right lobe is inked blue and the left lobe is inked black. The specimen is serially sectioned from right to left. The right lobe contains a previously incised tan-pink, friable, well-circumscribed nodule that is 2.7 x 2.2 x 2.0 cm. The nodule abuts the thyroid capsule and is not grossly encapsulated. A random section of the nodule is submitted for frozen section and resubmitted as received in cassette DF1. The left lobe contains a tan-white well-circumscribed nodule that is 0.6 x 0.5 x 0.5 cm. The left lobe nodule abuts the thyroid capsule and is not grossly encapsulated. The remaining cut surfaces of the thyroid are tan-pink and lobulated. 1

Summary of Cassettes: DF1, frozen section of right lobe nodule; D1-6, remainder of right lobe nodule; D7, entire left lobe nodule; D8, uninvolved right thyroid lobe; D9, isthmus; D10, uninvolved left thyroid lobe

■ The specimen is designated "right paratracheal lymph node" and consists of a 1.4 x 0.9 x 0.5 cm tan-pink lymph node. TE 1

Lab Use Only: ■

Gross description by: ■

Source: NCI Genomic Data Commons file c9466413-96ab-46bb-9edf-577028ee6897 (TCGA-FE-A23A.365B2777-B6AC-4B9B-A082-B209C61F9ACE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).